Somatic mutation profile of tumor specimen TCGA-WB-A822-01A (aliquot TCGA-WB-A822-01A-11D-A35I-08) from TCGA case TCGA-WB-A822, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 23.8 years (8,708 days).
Specimen TCGA-WB-A822-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ba58687-696a-470e-9e9e-c8333a058325.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A822-10A (Blood Derived Normal), aliquot TCGA-WB-A822-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/317d0972-6851-45d1-b094-be75edc74298

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGHD | c.193A>G p.M65V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPL38 | c.1114A>C p.S372R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); called by muse, varscan2
- UNC79 | c.3556G>A p.E1186K (on ENST00000393151 / NM_001346218.2; = p.E1009K on NM_020818.5) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); called by muse, mutect2
- PXDN | c.3393C>T p.P1131= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
